Somatic mutation profile of cancer-model specimen HCM-CSHL-0852-C76-85A (3D Organoid, passage 4; aliquot HCM-CSHL-0852-C76-85A-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0852-C76, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Tumor grade: GX.
Specimen HCM-CSHL-0852-C76-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7021f646-45a8-4990-8fbe-1f6dc5690aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0852-C76-10A (Blood Derived Normal), aliquot HCM-CSHL-0852-C76-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9ebeae8-7eb6-4599-a3e3-d577664f9d8f

The open-access MAF lists 189 somatic variants for this specimen: 135 protein-altering or splice-affecting, 49 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 49, Nonsense Mutation 9, Frame Shift Del 5, Intron 3, 3'UTR 2, In Frame Del 2, Splice Site 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 228/228 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52660939, COSV52789715, COSV53470581; called by muse, mutect2, varscan2
- AFF2 | c.3500A>G p.Y1167C | Missense Mutation (SNP) | VAF 276/276 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53994202; called by muse, mutect2, varscan2
- AIF1 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559066; called by muse, mutect2, varscan2
- BRINP3 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 225/430 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV66526063; called by muse, mutect2, varscan2
- CBLC | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 289/589 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs374048625; called by muse, mutect2, varscan2
- CEL | c.1154C>T p.T385M (on ENST00000673714; = p.T382M on NM_001807.6) | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs774313114; called by muse, mutect2
- CFAP65 | c.4775T>C p.L1592P | Missense Mutation (SNP) | VAF 256/556 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1230616629; called by muse, mutect2, varscan2
- CNTNAP5 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV70470945, COSV70502314; called by muse, mutect2, varscan2
- CTNNA2 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); catalogued as COSV100781809; called by muse, mutect2, varscan2
- DCAF6 | c.1471A>G p.I491V (on ENST00000312263 / NM_001349778.1; = p.I511V on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.376); catalogued as rs1002123951; called by muse, mutect2, varscan2
- DCC | c.1723-1G>T p.X575_splice | Splice Site (SNP) | VAF 88/88 reads (100%) | catalogued as COSV100498668; called by muse, mutect2, varscan2
- DECR1 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs770560957; called by muse, mutect2, varscan2
- DNAH2 | c.8212C>T p.R2738* | Nonsense Mutation (SNP) | VAF 118/119 reads (99%) | catalogued as rs1332489191, COSV66717577; called by muse, mutect2, varscan2
- EPB42 | c.638G>A p.R213H (on ENST00000441366 / NM_001114134.2; = p.R243H on NM_000119.3) | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs370874819, COSV100281939; called by muse, mutect2, varscan2
- FGFR1OP2 | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 135/310 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.313); catalogued as COSV57586577; called by muse, mutect2, varscan2
- GPA33 | c.697A>G p.M233V | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs964109007; called by muse, mutect2, varscan2
- GRIK2 | c.2546dup p.N849Kfs*11 | Frame Shift Ins (INS) | VAF 80/190 reads (42%) | catalogued as rs760757380; called by mutect2, varscan2
- HELT | c.69G>T p.R23S | Missense Mutation (SNP) | VAF 291/452 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378484343; called by muse, mutect2, varscan2
- IL17RE | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 134/215 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs912371200; called by muse, mutect2, varscan2
- KMT2A | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100629781; called by muse, mutect2, varscan2
- LRIG1 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV56238197; called by muse, mutect2, varscan2
- LRRIQ1 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1473157934, COSV67825469, COSV67829538; called by muse, mutect2, varscan2
- LRRTM4 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 144/284 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99081384; called by muse, mutect2, varscan2
- MATR3 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 139/300 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.027); catalogued as rs1190247069, COSV63078364; called by muse, mutect2, varscan2
- NLRP12 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs753099958, COSV60745068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU4F3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 125/333 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100047093; called by muse, mutect2, varscan2
- PTH2R | c.328del p.D110Ifs*6 | Frame Shift Del (DEL) | VAF 118/271 reads (44%) | catalogued as COSV55913638; called by mutect2, pindel, varscan2
- RND1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 200/451 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs267603489, COSV59045087; called by muse, mutect2, varscan2
- SCML4 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 304/600 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335530161; called by muse, mutect2
- SEMA4F | c.793A>C p.K265Q | Missense Mutation (SNP) | VAF 168/355 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as rs746931746; called by muse, mutect2, varscan2
- SLC35A1 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 143/310 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs578205635; called by muse, mutect2, varscan2
- SLC45A4 | c.2333C>T p.S778L (on ENST00000517878 / NM_001286646.2; = p.R725C on NM_001080431.2) | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.144); catalogued as rs151336979; called by muse, mutect2
- SNX33 | c.1708A>G p.M570V | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1203996056; called by muse, mutect2, varscan2
- TAL2 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV61883831; called by muse, mutect2
- TAS2R43 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 114/336 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV67858460; called by muse, mutect2, varscan2
- TBC1D22A | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 234/436 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1304770672; called by muse, mutect2, varscan2
- THOC1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 18/413 reads (4%) | catalogued as COSV55276050; called by muse, mutect2
- TLR4 | c.1449C>A p.F483L (on ENST00000355622 / NM_138554.5; = p.F443L on NM_003266.4) | Missense Mutation (SNP) | VAF 211/523 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV62922548; called by muse, mutect2, varscan2
- TMTC2 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 146/281 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV58272216; called by muse, mutect2, varscan2
- TP53 | c.480G>T p.M160I | Missense Mutation (SNP) | VAF 228/229 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.375); catalogued as COSV52849333, COSV53297171, COSV53424484, COSV53438638; called by muse, mutect2, varscan2
- UNC5D | c.2176G>T p.D726Y | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as rs779633938; called by muse, mutect2, varscan2
- URI1 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs201902251; called by muse, mutect2, varscan2
- USP19 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs768147710; called by muse, mutect2, varscan2
- VPS13B | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs1370447925, COSV100662627; called by muse, mutect2, varscan2
- ABCC10 | c.3626_3628del p.E1209del (on ENST00000372530 / NM_001198934.2; = p.E1181del on NM_033450.2 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 175/182 reads (96%) | called by pindel, varscan2
- ADGRL3 | c.2440G>T p.V814F (on ENST00000506720 / NM_001322402.2; = p.V746F on NM_015236.6) | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- AGAP1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 134/333 reads (40%) | called by muse, mutect2, varscan2
- AJM1 | c.1687C>T p.H563Y | Missense Mutation (SNP) | VAF 373/1055 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.3434G>C p.R1145P | Missense Mutation (SNP) | VAF 163/343 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4038A>T p.Q1346H | Missense Mutation (SNP) | VAF 218/435 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP23 | c.2245G>T p.G749C | Missense Mutation (SNP) | VAF 258/460 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ATAD2 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- BBS7 | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAN | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 206/616 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRSK2 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 226/513 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CA12 | c.557T>G p.I186S | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH18 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 204/404 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CFAP43 | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 142/341 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP45 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CNTNAP5 | c.1505G>T p.C502F | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL27A1 | c.5515G>C p.D1839H | Missense Mutation (SNP) | VAF 423/699 reads (61%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- COL6A5 | c.6226C>A p.L2076I (on ENST00000312481; = p.L2072I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/314 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DCAF4L2 | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 179/366 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DCUN1D4 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 175/430 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DENND3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 191/560 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- DMD | c.10704C>G p.H3568Q | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.12394A>T p.T4132S | Missense Mutation (SNP) | VAF 170/372 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- DNAI2 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 211/471 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DST | c.21668G>C p.R7223P (on ENST00000361203 / NM_001374722.1; = p.R4920P on NM_015548.5) | Missense Mutation (SNP) | VAF 158/385 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGF7 | c.150_157del p.E50Dfs*5 | Frame Shift Del (DEL) | VAF 123/264 reads (47%) | called by mutect2, pindel, varscan2
- FMN2 | c.3323C>A p.P1108H | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- FSIP2 | c.15578C>A p.S5193Y | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- GALNTL6 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 223/350 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- GTDC1 | c.153del p.T52Pfs*19 | Frame Shift Del (DEL) | VAF 101/247 reads (41%) | called by mutect2, pindel, varscan2
- GYPC | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 126/315 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HAO1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HARBI1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 175/389 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HEATR4 | c.2138G>C p.R713P | Missense Mutation (SNP) | VAF 123/332 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.6410G>T p.W2137L | Missense Mutation (SNP) | VAF 196/409 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HPS3 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 141/415 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL18R1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 146/313 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ING1 | c.475_477delinsAT p.R159Ifs*19 | Frame Shift Del (DEL) | VAF 266/270 reads (99%) | called by pindel, varscan2*
- INS-IGF2 | c.10T>A p.W4R | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- KCNA4 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 224/474 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KLB | c.1726T>C p.C576R | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KRT14 | c.1275-20_1292del p.X425_splice | Splice Site (DEL) | VAF 66/248 reads (27%) | called by mutect2, pindel, varscan2
- LCOR | c.3970C>T p.Q1324* | Nonsense Mutation (SNP) | VAF 157/310 reads (51%) | called by muse, mutect2, varscan2
- LRFN5 | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 178/363 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- LRP1B | c.13678C>T p.P4560S | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP1B | c.11179A>T p.R3727* | Nonsense Mutation (SNP) | VAF 82/186 reads (44%) | called by muse, mutect2, varscan2
- LTO1 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 177/6972 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2
- MAML1 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 245/527 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- MARK3 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 148/294 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MINAR1 | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 156/383 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NOVA2 | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 200/409 reads (49%) | called by muse, mutect2, varscan2
- NPAP1 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 141/309 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NYAP2 | c.249C>G p.H83Q | Missense Mutation (SNP) | VAF 120/319 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OPN5 | c.603_611del p.N202_L204del | In Frame Del (DEL) | VAF 168/179 reads (94%) | called by mutect2, pindel, varscan2
- OPRK1 | c.111C>G p.D37E | Missense Mutation (SNP) | VAF 333/684 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51S1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 178/382 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR6C2 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 171/349 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OTOA | c.3412C>T p.L1138F (on ENST00000286149; = p.L1124F on NM_144672.4) | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OTUD7B | c.2515C>A p.L839M | Missense Mutation (SNP) | VAF 135/286 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- PCDH17 | c.3209A>G p.Q1070R | Missense Mutation (SNP) | VAF 182/182 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PDE4D | c.1177G>A p.V393I (on ENST00000340635 / NM_001104631.2; = p.V257I on NM_006203.4) | Missense Mutation (SNP) | VAF 83/276 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCXD3 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PTPRD | c.2347C>A p.H783N | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by mutect2, varscan2
- RGPD4 | c.2920G>A p.D974N | Missense Mutation (SNP) | VAF 188/532 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2
- RGS20 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 147/329 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- RIMS1 | c.3400G>C p.G1134R | Missense Mutation (SNP) | VAF 114/241 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- RPS6KA2 | c.2112A>T p.R704S | Missense Mutation (SNP) | VAF 148/281 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR2 | c.1333G>C p.V445L | Missense Mutation (SNP) | VAF 163/303 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.9079A>T p.T3027S | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SART1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 143/203 reads (70%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SASH1 | c.2860G>C p.G954R | Missense Mutation (SNP) | VAF 214/438 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SBK3 | c.195G>T p.G65= | Splice Region (SNP) | VAF 154/314 reads (49%) | called by muse, mutect2, varscan2
- SELE | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 144/329 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SELENOP | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SLC22A7 | c.1387C>G p.Q463E (on ENST00000372585 / NM_153320.2; = p.Q461E on NM_006672.3) | Missense Mutation (SNP) | VAF 138/204 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC36A2 | c.1085C>A p.A362E | Missense Mutation (SNP) | VAF 181/366 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SNRPD2 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 158/354 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TLR5 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 194/386 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TMOD4 | c.377C>A p.A126D | Missense Mutation (SNP) | VAF 158/362 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TOPAZ1 | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TPH2 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 94/203 reads (46%) | called by muse, mutect2, varscan2
- UBE3A | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 85/268 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USH2A | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 153/306 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- XKR4 | c.1631G>C p.S544T | Missense Mutation (SNP) | VAF 158/346 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by mutect2, varscan2
- YARS1 | c.1517A>T p.K506M | Missense Mutation (SNP) | VAF 202/204 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZFHX4 | c.1063G>T p.G355* | Nonsense Mutation (SNP) | VAF 53/393 reads (13%) | called by muse, mutect2, varscan2
- ZFYVE16 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 134/299 reads (45%) | called by muse, mutect2, varscan2
- ZNF28 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF33B | c.1767C>G p.I589M | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF586 | c.541del p.I181Lfs*73 | Frame Shift Del (DEL) | VAF 160/422 reads (38%) | called by mutect2, pindel, varscan2
- ZNF80 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 61/539 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ADAMTS16 | c.2796C>G p.S932= | Silent (SNP) | VAF 125/262 reads (48%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2916G>T p.G972= (on ENST00000506720 / NM_001322402.2; = p.G904= on NM_015236.6) | Silent (SNP) | VAF 148/297 reads (50%) | catalogued as COSV101546911, COSV72230217; called by muse, mutect2, varscan2
- ANKRD31 | c.2340G>A p.L780= | Silent (SNP) | VAF 163/359 reads (45%) | called by muse, mutect2
- ARHGAP23 | c.474C>A p.I158= | Silent (SNP) | VAF 243/549 reads (44%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.1590C>A p.L530= | Silent (SNP) | VAF 262/262 reads (100%) | called by muse, mutect2, varscan2
- ATG2A | c.3195G>A p.V1065= | Silent (SNP) | VAF 160/339 reads (47%) | called by muse, mutect2, varscan2
- BPIFB1 | c.261G>A p.L87= | Silent (SNP) | VAF 89/310 reads (29%) | called by muse, mutect2, varscan2
- C8A | c.102C>G p.P34= | Silent (SNP) | VAF 119/119 reads (100%) | catalogued as COSV100776556, COSV63484173; called by muse, mutect2, varscan2
- CACNA1F | c.1065T>A p.L355= | Silent (SNP) | VAF 305/305 reads (100%) | called by muse, mutect2, varscan2
- CACNG6 | c.54G>T p.A18= | Silent (SNP) | VAF 303/537 reads (56%) | catalogued as COSV99403701; called by muse, mutect2, varscan2
- CCDC146 | c.1701A>G p.L567= | Silent (SNP) | VAF 196/196 reads (100%) | catalogued as rs1450590677; called by muse, mutect2, varscan2
- CDC42EP4 | c.477G>A p.T159= | Silent (SNP) | VAF 173/506 reads (34%) | catalogued as rs757049831; called by muse, mutect2, varscan2
- CDH9 | c.438C>T p.I146= | Silent (SNP) | VAF 132/338 reads (39%) | catalogued as COSV50260364; called by muse, mutect2, varscan2
- CENPU | c.507G>A p.A169= | Silent (SNP) | VAF 136/466 reads (29%) | catalogued as rs368662408; called by muse, mutect2, varscan2
- CLEC4F | c.1510C>T p.L504= | Silent (SNP) | VAF 184/365 reads (50%) | catalogued as COSV99713845; called by muse, mutect2, varscan2
- CNGA3 | c.756T>C p.D252= | Silent (SNP) | VAF 119/260 reads (46%) | called by muse, mutect2, varscan2
- DNAJC13 | c.5034C>G p.V1678= | Silent (SNP) | VAF 120/211 reads (57%) | called by muse, mutect2, varscan2
- EFCAB8 | c.747C>G p.V249= | Silent (SNP) | VAF 160/371 reads (43%) | called by muse, mutect2, varscan2
- FSIP2 | c.15579C>A p.S5193= | Silent (SNP) | VAF 65/169 reads (38%) | called by muse, mutect2, varscan2
- FSTL5 | c.393A>G p.E131= | Silent (SNP) | VAF 72/279 reads (26%) | called by muse, mutect2, varscan2
- GABRG2 | c.84G>A p.L28= | Silent (SNP) | VAF 76/203 reads (37%) | called by muse, mutect2, varscan2
- GPIHBP1 | c.516C>A p.L172= | Silent (SNP) | VAF 260/334 reads (78%) | catalogued as COSV58209184; called by muse, mutect2, varscan2
- HDLBP | c.2541C>A p.V847= | Silent (SNP) | VAF 30/496 reads (6%) | called by muse, mutect2
- HSPA14 | c.246A>G p.K82= | Silent (SNP) | VAF 87/87 reads (100%) | called by muse, mutect2, varscan2
- IFT52 | c.1030C>A p.R344= | Silent (SNP) | VAF 123/252 reads (49%) | called by muse, mutect2, varscan2
- IRX1 | c.258C>T p.L86= | Silent (SNP) | VAF 181/368 reads (49%) | called by muse, mutect2, varscan2
- KDM4E | c.381C>A p.P127= | Silent (SNP) | VAF 215/248 reads (87%) | catalogued as rs781915167; called by muse, mutect2
- LRFN5 | c.57C>T p.I19= | Silent (SNP) | VAF 150/280 reads (54%) | catalogued as rs759304038, COSV53244968; called by muse, mutect2, varscan2
- MED24 | c.2454C>G p.L818= | Silent (SNP) | VAF 100/339 reads (29%) | called by muse, mutect2, varscan2
- MYO15B | c.3429G>A p.P1143= | Silent (SNP) | VAF 177/400 reads (44%) | catalogued as rs1445048585; called by muse, mutect2, varscan2
- OLR1 | c.33G>C p.V11= | Silent (SNP) | VAF 126/282 reads (45%) | catalogued as rs1247827991, COSV58872750; called by muse, mutect2, varscan2
- PCDHB8 | c.750G>A p.V250= | Silent (SNP) | VAF 149/333 reads (45%) | called by muse, mutect2, varscan2
- PLCH1 | c.1513C>A p.R505= (on ENST00000340059 / NM_001130960.2; = p.R517= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 299/717 reads (42%) | catalogued as rs370011945, COSV58204302; called by muse, mutect2, varscan2
- PLEC | c.6159G>A p.T2053= (on ENST00000322810 / NM_201380.4; = p.T1943= on NM_000445.5) | Silent (SNP) | VAF 406/503 reads (81%) | catalogued as rs372415930; called by muse, mutect2, varscan2
- PPFIA2 | c.2523A>G p.K841= | Silent (SNP) | VAF 102/203 reads (50%) | catalogued as rs1463541284; called by muse, varscan2
- PRRC2C | c.5451C>T p.V1817= (on ENST00000367742; = p.V1815= on NM_015172.4) | Silent (SNP) | VAF 271/599 reads (45%) | catalogued as rs1277521503; called by muse, mutect2, varscan2
- PRUNE2 | c.9213A>T p.P3071= | Silent (SNP) | VAF 122/369 reads (33%) | called by muse, mutect2, varscan2
- PTPRB | c.4017C>G p.S1339= | Silent (SNP) | VAF 263/525 reads (50%) | catalogued as COSV54237986; called by muse, mutect2, varscan2
- RFLNB | c.294C>T p.I98= | Silent (SNP) | VAF 258/259 reads (100%) | catalogued as rs782508006, COSV61239269; called by muse, mutect2, varscan2
- SPHK2 | c.705G>C p.L235= | Silent (SNP) | VAF 150/306 reads (49%) | called by muse, mutect2, varscan2
- SSTR5 | c.165G>A p.L55= | Silent (SNP) | VAF 349/350 reads (100%) | catalogued as COSV53511560; called by muse, mutect2, varscan2
- TASOR | c.1824G>T p.R608= (on ENST00000355628 / NM_001365636.2; = p.R212= on NM_015224.3) | Silent (SNP) | VAF 87/87 reads (100%) | catalogued as rs1215837416; called by muse, mutect2, varscan2
- TBK1 | c.297A>G p.E99= | Silent (SNP) | VAF 67/162 reads (41%) | called by muse, mutect2, varscan2
- TDP1 | c.453C>T p.G151= | Silent (SNP) | VAF 214/443 reads (48%) | catalogued as rs745601038; called by muse, mutect2, varscan2
- TEFM | c.726T>A p.S242= | Silent (SNP) | VAF 169/346 reads (49%) | called by muse, mutect2, varscan2
- TSC22D2 | c.1590T>C p.N530= | Silent (SNP) | VAF 248/808 reads (31%) | catalogued as rs1446117158; called by muse, mutect2, varscan2
- XIRP1 | c.3577C>A p.R1193= | Silent (SNP) | VAF 231/231 reads (100%) | called by muse, mutect2, varscan2
- ZBED3 | c.327C>T p.S109= | Silent (SNP) | VAF 268/586 reads (46%) | called by muse, mutect2, varscan2
- ZNF804A | c.2616A>T p.T872= | Silent (SNP) | VAF 155/347 reads (45%) | called by muse, mutect2, varscan2
- ASB14 | c.736-9C>G | Intron (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.102-1151G>A | Intron (SNP) | VAF 222/495 reads (45%) | called by muse, mutect2, varscan2
- MYOG | c.*226C>A | 3'UTR (SNP) | VAF 128/299 reads (43%) | called by muse, mutect2, varscan2
- OGA | c.1984+45C>T | Intron (SNP) | VAF 130/282 reads (46%) | called by muse, mutect2, varscan2
- SDF2L1 | c.*2_*7del | 3'UTR (DEL) | VAF 125/259 reads (48%) | called by mutect2, pindel, varscan2
